Somatic mutation profile of tumor specimen TARGET-30-PAUXIW-09A (aliquot TARGET-30-PAUXIW-09A-01D) from TARGET case TARGET-30-PAUXIW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (822 days).
Specimen TARGET-30-PAUXIW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52d65b50-7d26-4f68-b718-9c30506ad56b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUXIW-10A (Blood Derived Normal), aliquot TARGET-30-PAUXIW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3996861f-3ef1-4d08-80a2-387cd74e59f7

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT5B | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs748297446, COSV58564589; called by muse, mutect2, varscan2
